Somatic mutation profile of tumor specimen TCGA-86-A4D0-01A (aliquot TCGA-86-A4D0-01A-11D-A24D-08) from TCGA case TCGA-86-A4D0, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 48.2 years (17,607 days).
Specimen TCGA-86-A4D0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93ebfbac-d457-41f8-9fa1-1b65c4589fc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-A4D0-10A (Blood Derived Normal), aliquot TCGA-86-A4D0-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ab3b1d5-6990-4918-9cfb-77e3a749d199

The open-access MAF lists 287 somatic variants for this specimen: 216 protein-altering or splice-affecting, 62 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 62, Nonsense Mutation 16, Frame Shift Del 7, Splice Site 4, RNA 3, 5'Flank 2, Intron 2, 3'Flank 1, In Frame Del 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 34/49 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260583; called by muse, mutect2, varscan2
- STK11 | c.157dup p.D53Gfs*110 | Frame Shift Ins (INS) | VAF 17/30 reads (57%) | catalogued as rs1131690917; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 52/106 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ACAN | c.5470G>A p.G1824S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs375361510, COSV100717742; called by muse, mutect2, varscan2
- ACOX3 | c.1311G>T p.L437F | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.651); catalogued as rs1337653132; called by muse, mutect2, varscan2
- ANK3 | c.10467G>T p.K3489N | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as COSV99780934; called by muse, mutect2, varscan2
- AP4B1 | c.639G>T p.W213C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99871134; called by mutect2, varscan2
- ASXL1 | c.1669A>G p.T557A | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1185741428; called by muse, mutect2
- BBS9 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as rs1399134427; called by muse, mutect2, varscan2
- BRWD1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1165512556; called by muse, mutect2
- CCKBR | c.1289T>C p.I430T | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1377861254; called by muse, mutect2, varscan2
- CEMIP2 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1037438500; called by muse, mutect2, varscan2
- CIZ1 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 30/91 reads (33%) | catalogued as rs769502179; called by muse, mutect2, varscan2
- CLDN2 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV61020612; called by muse, mutect2, varscan2
- CLDN8 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.024); catalogued as rs753299149; called by muse, mutect2, varscan2
- CNTNAP4 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs1344229735; called by muse, mutect2
- DDX23 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1418397334, COSV57284916, COSV57286745; called by muse, mutect2, varscan2
- DISP3 | c.3733G>A p.V1245I | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747070416, COSV99610388; called by muse, mutect2, varscan2
- DNAH9 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs778510475, COSV52361365; called by muse, mutect2
- DSCAM | c.3121G>T p.D1041Y | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs748310632; called by muse, mutect2, varscan2
- DYNC1H1 | c.7676C>T p.T2559M | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1324450395, COSV64139540; called by muse, mutect2, varscan2
- DYNC1H1 | c.12853G>C p.A4285P | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100795476; called by mutect2, varscan2
- DZIP1L | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100551365; called by muse, mutect2, varscan2
- EPHA5 | c.2310del p.Q771Sfs*4 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as COSV56672570; called by mutect2, pindel, varscan2
- EXOC6B | c.2083G>T p.A695S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs766942278; called by muse, mutect2, varscan2
- FSCN3 | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV56169377; called by muse, mutect2, varscan2
- GABRA5 | c.183C>A p.D61E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59482616; called by muse, mutect2, varscan2
- GLDC | c.2890T>G p.Y964D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs916926569; called by muse, mutect2, varscan2
- GTPBP10 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 60/173 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); catalogued as rs776494042; called by muse, mutect2, varscan2
- IGSF22 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs933814811; called by muse, mutect2, varscan2
- ISL1 | c.610C>G p.P204A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV57935157; called by muse, mutect2, varscan2
- JPH1 | c.1652A>G p.H551R | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs887759025; called by muse, mutect2
- KMT2C | c.2045C>T p.S682L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51435734; called by muse, mutect2, varscan2
- KRT1 | c.1378C>A p.R460S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52868370; called by muse, mutect2, varscan2
- KRTAP1-1 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756291377, COSV60397991; called by muse, mutect2, varscan2
- LAMA2 | c.3460G>A p.G1154R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756475916, COSV70348110; called by muse, mutect2, varscan2
- LMO7 | c.3257C>T p.S1086L (on ENST00000357063; = p.S767L on NM_005358.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs1296631066; called by muse, mutect2
- LRIT2 | c.1394A>G p.H465R | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765371341; called by muse, mutect2, varscan2
- LURAP1L | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1279935483; called by muse, mutect2, varscan2
- MBIP | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs758726043, COSV59255281; called by muse, mutect2
- MRC2 | c.2911G>T p.G971C | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1429861463; called by muse, mutect2
- MSRB3 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267603630, COSV57589447; called by muse, mutect2, varscan2
- MTOR | c.7149G>T p.L2383F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63879664; called by muse, mutect2, varscan2
- MYH7B | c.5882C>T p.A1961V | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762950642, COSV99327793; called by muse, mutect2, varscan2
- NBPF26 | c.4117C>G p.L1373V (on ENST00000620612; = p.L1111V on NM_001351372.1) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1553273419; called by muse, mutect2
- NR6A1 | c.394G>T p.E132* (on ENST00000487099 / NM_033334.4; = p.E128* on NM_001489.5) | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV60631470; called by muse, mutect2, varscan2
- OR2M5 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV63546287; called by muse, varscan2
- OR51E1 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67809809; called by muse, mutect2, varscan2
- OR5D18 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100450954, COSV61737830; called by muse, mutect2, varscan2
- OR5L1 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.17); catalogued as rs762657420; called by muse, mutect2, varscan2
- PCDHGB7 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs1304962440; called by muse, mutect2, varscan2
- PDHA2 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.501); catalogued as COSV54782497; called by muse, mutect2, varscan2
- PHKA2 | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 61/82 reads (74%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs1192881117; called by muse, mutect2, varscan2
- PTPRD | c.5279C>A p.A1760E | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV61979862; called by muse, mutect2, varscan2
- QSER1 | c.1439G>T p.R480L (on ENST00000399302; = p.R609L on NM_001076786.3) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV101234999; called by muse, mutect2, varscan2
- RALYL | c.201T>A p.H67Q | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV72817156; called by muse, mutect2, varscan2
- RNF216 | c.838G>A p.D280N (on ENST00000425013 / NM_207116.3; = p.D337N on NM_207111.4) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1216254834; called by muse, mutect2, varscan2
- RYR2 | c.12290A>G p.N4097S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs794728784, CM045194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUN1 | c.1898G>A p.R633H (on ENST00000405266 / NM_001367651.1; = p.R513H on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs372947867; called by muse, mutect2, varscan2
- SVEP1 | c.9416C>A p.T3139N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV52837547; called by muse, mutect2, varscan2
- TAS2R60 | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV60332519; called by muse, mutect2, varscan2
- TBX2 | c.1833C>A p.F611L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV53597584; called by muse, mutect2, varscan2
- TENT4A | c.2197A>G p.M733V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs756780526; called by muse, mutect2, varscan2
- TMEM179B | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as rs781136892; called by muse, mutect2, varscan2
- TPSAB1 | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as rs1185538951; called by muse, mutect2, varscan2
- TUBA1A | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55497512; called by muse, mutect2, varscan2
- UNC13B | c.4714G>T p.E1572* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as rs1025861126, COSV61470555; called by muse, varscan2
- UTP18 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs754613905; called by muse, mutect2, varscan2
- VNN2 | c.581C>A p.P194Q | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs776443567; called by muse, mutect2, varscan2
- YBX2 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 126/251 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV50301998; called by muse, mutect2, varscan2
- ZFPM2 | c.2365G>T p.D789Y | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV65873784; called by muse, mutect2
- ZNF518B | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs1380410394, COSV100456712; called by muse, mutect2, varscan2
- ZNF653 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53402657; called by muse, mutect2, varscan2
- ABCA10 | c.2834G>T p.C945F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADAM23 | c.1457G>T p.R486I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ADAM29 | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADD2 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2
- AKAP14 | c.242A>T p.Q81L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ALG10 | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- AMER1 | c.2418G>T p.M806I | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ANGPT1 | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 66/94 reads (70%) | called by muse, mutect2, varscan2
- ANK2 | c.5779C>T p.P1927S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ANKRD7 | c.661G>C p.G221R | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- ARAF | c.679A>T p.M227L | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1B | c.3643G>T p.G1215C | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- BAAT | c.291G>T p.M97I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- BAIAP2L2 | c.440G>T p.R147I | Missense Mutation (SNP) | VAF 21/668 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BAZ2B | c.5197G>T p.V1733L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- BRINP1 | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA1S | c.2180C>A p.S727Y | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- CCKAR | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CDK14 | c.1259G>T p.S420I (on ENST00000380050 / NM_001287135.2; = p.S402I on NM_012395.3) | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CEP135 | c.1557G>T p.M519I | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.207); called by muse, varscan2
- CFAP53 | c.1322A>C p.Q441P | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.116); called by muse, mutect2
- CFAP54 | c.7448T>A p.L2483Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CIZ1 | c.1229A>T p.Q410L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CNTN6 | c.711A>G p.I237M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COMMD1 | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- CPA2 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRLF2 | c.558G>T p.R186S | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD3 | c.3380G>T p.G1127V (on ENST00000297405 / NM_001363185.1; = p.G1023V on NM_052900.3) | Missense Mutation (SNP) | VAF 78/103 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CYP26B1 | c.314T>A p.I105N | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DCAF4L2 | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.138); called by muse, mutect2
- DCAF5 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- DCDC1 | c.938T>A p.V313E | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DLG5 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- DNAH2 | c.10610T>C p.L3537P | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH7 | c.6705A>C p.E2235D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK10 | c.1792G>T p.V598L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DOCK10 | c.843G>A p.W281* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- DOCK7 | c.2718del p.T907Lfs*18 (on ENST00000635253 / NM_001367561.1; = p.T907Lfs*38 on NM_033407.3) | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- DSG2 | c.1535A>C p.Y512S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- DYNC1H1 | c.6694A>C p.M2232L | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- E2F2 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERICH3 | c.3177G>T p.E1059D | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ETNPPL | c.1404G>T p.R468S | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCA | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- FLG | c.6341G>C p.R2114T | Missense Mutation (SNP) | VAF 16/347 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.035); called by muse, mutect2
- FMO4 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- H2AC20 | c.23G>C p.G8A | Missense Mutation (SNP) | VAF 17/300 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.071); called by muse, mutect2
- HERC2 | c.6474G>T p.Q2158H | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- HSPG2 | c.6631G>C p.A2211P | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2
- ICE1 | c.6317G>T p.G2106V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGLV7-46 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1723G>A p.V575I | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- IRX4 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 53/102 reads (52%) | called by muse, mutect2, varscan2
- KCNH1 | c.2480del p.G827Afs*48 (on ENST00000271751 / NM_172362.3; = p.G800Afs*48 on NM_002238.4) | Frame Shift Del (DEL) | VAF 44/170 reads (26%) | called by mutect2, pindel, varscan2
- KCNJ2 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNT2 | c.2180C>G p.T727R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIF14 | c.3461A>G p.Y1154C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIF1C | c.1447del p.V483Sfs*20 | Frame Shift Del (DEL) | VAF 50/138 reads (36%) | called by mutect2, pindel, varscan2
- KPRP | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- KRT78 | c.1293G>T p.Q431H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- KSR1 | c.682A>G p.I228V (on ENST00000644974 / NM_001367810.1; = p.I91V on NM_014238.2) | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC4C | c.1609A>C p.T537P | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCF2 | c.2047G>T p.G683C | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MDC1 | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2
- MEMO1 | c.698del p.S233Tfs*4 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- MEMO1 | c.694_696dup p.F232dup | In Frame Ins (INS) | VAF 14/41 reads (34%) | called by mutect2, pindel*, varscan2
- MKS1 | c.1226G>C p.R409T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2B | c.3934G>T p.A1312S | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MRPL35 | c.43+1G>T p.X15_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- N4BP2 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEURL1 | c.1535_1547del p.P512Rfs*80 | Frame Shift Del (DEL) | VAF 48/149 reads (32%) | called by mutect2, pindel, varscan2
- NFIB | c.494A>G p.Q165R | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NLRP1 | c.1049C>A p.A350D | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NOBOX | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.173); called by muse, mutect2
- NOX4 | c.630-1G>T p.X210_splice | Splice Site (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- NPAP1 | c.3299G>C p.S1100T | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NPRL3 | c.1511C>G p.A504G (on ENST00000611875 / NM_001077350.3; = p.A479G on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NUP98 | c.2978T>A p.I993N (on ENST00000359171 / NM_001365126.1; = p.I976N on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OBSCN | c.17035G>T p.E5679* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- OLFML2B | c.1442C>A p.P481H | Missense Mutation (SNP) | VAF 110/229 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- OR2B11 | c.254T>A p.M85K | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- OR4C46 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); called by muse, mutect2
- OR4K13 | c.526A>T p.S176C | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR51A2 | c.636T>G p.F212L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- OR51B5 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- OR52E4 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- OR7G2 | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 47/69 reads (68%) | called by muse, mutect2, varscan2
- OR8H2 | c.579C>A p.Y193* | Nonsense Mutation (SNP) | VAF 58/187 reads (31%) | called by muse, mutect2, varscan2
- PAK3 | c.1453G>T p.A485S (on ENST00000262836 / NM_001324328.2; = p.A470S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PCDHB13 | c.2057T>A p.L686H | Missense Mutation (SNP) | VAF 128/378 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PCDHB5 | c.1348T>C p.F450L | Missense Mutation (SNP) | VAF 106/303 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB8 | c.1322T>A p.L441Q | Missense Mutation (SNP) | VAF 90/584 reads (15%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDE3B | c.1874C>A p.T625K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDGFD | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHKB | c.1880G>T p.R627I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- PKDREJ | c.4910G>A p.R1637K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2
- PKHD1 | c.2755G>T p.G919C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLB1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAD51AP2 | c.2274G>C p.M758I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2
- RANBP6 | c.2275G>C p.D759H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RARS2 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- RBM6 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RBP3 | c.299del p.P100Hfs*45 | Frame Shift Del (DEL) | VAF 41/137 reads (30%) | called by mutect2, pindel, varscan2
- RIT2 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- RPUSD2 | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 28/46 reads (61%) | called by muse, mutect2, varscan2
- SERINC3 | c.700T>A p.C234S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC1 | c.4320G>T p.L1440F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- SLC24A2 | c.231G>T p.R77S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC5A7 | c.1373C>A p.P458H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SNAP91 | c.421A>T p.M141L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SOX6 | c.1435G>C p.D479H (on ENST00000528429 / NM_001145819.2; = p.G438R on NM_017508.3) | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SPATA31E1 | c.1961T>A p.L654Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SPTA1 | c.5096_5099delinsG p.Q1699_E1700delinsR | In Frame Del (DEL) | VAF 20/94 reads (21%) | called by pindel, varscan2*
- SS18 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- SUSD1 | c.126C>G p.C42W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SV2C | c.1619C>A p.T540N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SYT3 | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX44 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2
- TMEM256 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.01); called by muse, mutect2
- TMPRSS15 | c.2398G>T p.V800L | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- TRAV8-3 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- TRAV8-3 | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TRBC2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- TRIM37 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TSHZ2 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- TSNAXIP1 | c.1076C>A p.S359* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- TSPAN11 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UBQLN3 | c.1753T>A p.S585T | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBQLNL | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBR2 | c.1858+1G>A p.X620_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- UGT2B4 | c.1208T>G p.I403S | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- UNC80 | c.604T>A p.S202T | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UROC1 | c.602+1G>A p.X201_splice | Splice Site (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- VCAN | c.6763G>T p.G2255* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- VSX1 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZFHX4 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2
- ZFP57 | c.1480G>T p.G494W | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF185 | c.1601G>C p.S534T | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ZNF236 | c.3728G>T p.R1243L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF277 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF347 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZP4 | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS2 | c.198C>A p.A66= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2
- AGAP2 | c.1782G>T p.P594= (on ENST00000547588 / NM_001122772.2; = p.P258= on NM_014770.4) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs776594813; called by muse, mutect2
- ALOXE3 | c.48C>A p.A16= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1244707427; called by muse, mutect2, varscan2
- ANKRD34B | c.729C>A p.P243= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- C6orf118 | c.1012C>T p.L338= | Silent (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- CCDC54 | c.720C>T p.Y240= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV53758085; called by muse, mutect2, varscan2
- CDH24 | c.1062C>A p.P354= | Silent (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- CHD6 | c.1386G>T p.R462= | Silent (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- CPLX3 | c.381C>A p.A127= | Silent (SNP) | VAF 20/30 reads (67%) | called by muse, mutect2, varscan2
- CPPED1 | c.465C>A p.V155= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV99903352; called by muse, mutect2, varscan2
- CSMD1 | c.6153C>A p.P2051= (on ENST00000520002; = p.P2050= on NM_033225.6) | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs377629790, COSV59305521; called by muse, mutect2, varscan2
- DLGAP2 | c.2913C>A p.L971= | Silent (SNP) | VAF 33/50 reads (66%) | called by muse, mutect2, varscan2
- DSC2 | c.444C>T p.S148= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- DSG1 | c.81C>A p.I27= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV57138881; called by muse, mutect2, varscan2
- EPHA5 | c.1137G>T p.P379= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs747980985, COSV56654107, COSV56669678; called by muse, mutect2, varscan2
- FAAP100 | c.1770C>T p.G590= | Silent (SNP) | VAF 84/165 reads (51%) | catalogued as rs760397674, COSV59883948; called by muse, mutect2, varscan2
- FAM71B | c.1032C>A p.A344= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV100262158; called by muse, mutect2, varscan2
- GABRB2 | c.1167C>A p.T389= | Silent (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- GANAB | c.1134A>G p.Q378= | Silent (SNP) | VAF 68/156 reads (44%) | called by muse, mutect2, varscan2
- GCN1 | c.3519G>T p.A1173= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV100324600; called by muse, mutect2, varscan2
- GRAMD4 | c.1281G>A p.P427= | Silent (SNP) | VAF 91/174 reads (52%) | catalogued as rs571722030, COSV63029264; called by muse, mutect2, varscan2
- HCN1 | c.2343G>T p.R781= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs575150344, COSV57502099; called by muse, mutect2, varscan2
- HNF4G | c.447C>G p.V149= (on ENST00000354370 / NM_001330561.2; = p.V196= on NM_004133.5) | Silent (SNP) | VAF 88/122 reads (72%) | called by muse, mutect2, varscan2
- HYDIN | c.9990C>A p.T3330= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- IGLC2 | c.243C>T p.S81= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs372400558; called by muse, mutect2, varscan2
- IL21R | c.69C>T p.L23= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs202066831; called by muse, mutect2, varscan2
- ISLR2 | c.1071A>T p.A357= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
- KCNB2 | c.1860G>T p.P620= | Silent (SNP) | VAF 201/313 reads (64%) | catalogued as COSV73049642; called by muse, mutect2, varscan2
- KIF26A | c.903T>A p.A301= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- KLHL14 | c.1011C>G p.L337= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV63835062; called by muse, mutect2, varscan2
- LCE3A | c.228C>G p.G76= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as rs112433050; called by muse, mutect2, varscan2
- LIMS1 | c.54G>A p.A18= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs533409674, COSV57539640; called by muse, mutect2, varscan2
- MATK | c.1290G>A p.L430= (on ENST00000310132 / NM_139355.3; = p.L431= on NM_002378.4) | Silent (SNP) | VAF 43/64 reads (67%) | called by muse, mutect2, varscan2
- MMP16 | c.1020C>A p.P340= | Silent (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- MOS | c.414C>A p.I138= | Silent (SNP) | VAF 377/512 reads (74%) | catalogued as COSV100322682; called by muse, mutect2, varscan2
- MRC2 | c.2910G>T p.G970= | Silent (SNP) | VAF 2/11 reads (18%) | called by muse, mutect2
- NLRP12 | c.2766C>T p.I922= | Silent (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- NPAS4 | c.204T>G p.L68= | Silent (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- OR2B3 | c.663A>T p.I221= | Silent (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- OR2T1 | c.270C>A p.T90= | Silent (SNP) | VAF 56/172 reads (33%) | catalogued as COSV100822342; called by muse, mutect2, varscan2
- PCDHA4 | c.1608C>G p.T536= | Silent (SNP) | VAF 73/218 reads (33%) | catalogued as COSV63539543; called by muse, mutect2, varscan2
- PCDHB10 | c.1089G>T p.T363= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs1554284127, COSV53375219; called by muse, mutect2, varscan2
- PLXNA4 | c.5319G>T p.V1773= | Silent (SNP) | VAF 47/117 reads (40%) | called by muse, mutect2, varscan2
- POTEF | c.99C>A p.P33= | Silent (SNP) | VAF 119/267 reads (45%) | catalogued as COSV62543902; called by muse, mutect2, varscan2
- PRKDC | c.1944A>G p.S648= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as rs1375028377; called by muse, mutect2
- RABGAP1L | c.567G>T p.V189= | Silent (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- RFX7 | c.1257C>T p.V419= (on ENST00000559447 / NM_001368074.1; = p.V516= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs762526837; called by muse, mutect2, varscan2
- SEMA5A | c.1167G>T p.V389= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- SLC4A1 | c.978C>T p.A326= | Silent (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2
- SMG1 | c.5368T>C p.L1790= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- SOX5 | c.648G>C p.L216= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs775858000; called by muse, mutect2, varscan2
- TBC1D8B | c.2763A>G p.K921= | Silent (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- TDRD6 | c.948G>T p.P316= | Silent (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- TMTC1 | c.2631A>T p.R877= (on ENST00000539277 / NM_001193451.2; = p.R769= on NM_175861.3) | Silent (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- TMTC1 | c.849A>T p.G283= (on ENST00000539277 / NM_001193451.2; = p.G175= on NM_175861.3) | Silent (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- UBA1 | c.1356C>T p.D452= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs375669736, COSV60115813; ClinVar: likely benign; called by muse, mutect2, varscan2
- UST | c.378G>A p.S126= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs772293025; called by muse, mutect2, varscan2
- UTP14C | c.2175C>T p.G725= | Silent (SNP) | VAF 42/67 reads (63%) | called by muse, mutect2, varscan2
- VPS13D | c.3519G>A p.L1173= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- ZFHX4 | c.603C>T p.L201= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs954096599, COSV99266531; called by muse, mutect2
- ZNF23 | c.1167G>A p.E389= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- ZNF770 | c.208C>T p.L70= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV62543833; called by muse, mutect2
- CTBP1 | chr4:1250988 G>T | 5'Flank (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- DZANK1 | c.543+685T>A | Intron (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.188G>A | RNA (SNP) | VAF 36/140 reads (26%) | called by mutect2, varscan2
- IGKV1-13 | n.187A>T | RNA (SNP) | VAF 36/140 reads (26%) | called by mutect2, varscan2
- NXF5 | n.1397C>T | RNA (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- SEC22C | c.*4629G>T | 3'UTR (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- SMIM12 | chr1:34855413 C>T | 3'Flank (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23443G>T | Intron (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173865668 T>A | 5'Flank (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
